Surgical pathology report (de-identified scan), TCGA case TCGA-Z6-A8JD, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Cureline, specimen TCGA-Z6-A8JD-01A (Primary Tumor).

ICD O-3

Carcinoma, squamous cell NOS
8070/3

Esophagitis NOS C15.9

9/11/27/14

Case #

Patient: Age (years): Gender: M

Clinical diagnosis: Esophageal cancer

Date of procurement:

Sample:

Gross description: Fragment of the esophagus (medial and proximal part) 15 cm and stomach length 2 cm. 1cm from proximal resection line. 10 cm from distal. Esophageal wall shows infiltrative-ulcerative tumor 4 cm in length, 5 cm in diameter. Section shows dense, stellate tumor. Esophageal and gastric mucosa shows no signs of invasion, has shiny smooth surface. Adjacent adipose tissue contains 5 consolidations 1 cm in diameter, black appearance. Paragastral and paraesophageal adipose tissue shows no signs of tumor growth.

Microscopic description: Section of infiltrative ulcerative tumor consistent with squamous carcinoma, moderately differentiated infiltrating all esophageal laminae and adventitia. Surgical margins are clear. Paragastral and paraesophageal lymphatic nodes show no signs of tumor growth. Greater omentum shows no signs of tumor growth.

Final diagnosis: Squamous cell carcinoma of the esophagus, grade 2

Confidential

Case is Ineligible		

Source: NCI Genomic Data Commons file 6e28f807-2c83-4878-9858-38e0aa6a07ea (TCGA-Z6-A8JD.E402EAB8-2336-4355-B627-C40AF1B64050.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).